Somatic mutation profile of tumor specimen 0DPX3Q from CCDI case PBCDPH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 8.9 years (3,256 days).
Specimen 0DPX3Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31778a06-08fa-44ac-8e30-27c0c233b1d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX35 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d9c07b3-fef4-499b-9581-a81a586ad442

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TENM4 | c.4744A>G p.I1582V | Missense Mutation (SNP) | VAF 105/231 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs758518569; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- IPO7 | c.2965del p.R989Efs*7 | Frame Shift Del (DEL) | VAF 157/479 reads (33%) | called by mutect2, pindel, varscan2
- PXDNL | c.4191T>G p.D1397E | Missense Mutation (SNP) | VAF 177/438 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPR179 | c.523C>T p.L175= | Silent (SNP) | VAF 112/230 reads (49%) | catalogued as rs373911359; called by muse, mutect2, varscan2
- TTN | c.2019G>A p.L673= (on ENST00000591111; = p.L627= on NM_003319.4) | Silent (SNP) | VAF 165/371 reads (44%) | catalogued as rs1438888698; called by muse, mutect2, varscan2
- CYP17A1 | c.*68_*69del | 3'UTR (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
